Gene-level copy-number profile of tumor specimen ALCH-ADRK-TTP1-A from ALCHEMIST case ALCH-ADRK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.6 years (23,246 days).
Specimen ALCH-ADRK-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2a84b4a5-d36e-4fa1-8745-0d933ef3a64e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADRK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/0747ffce-f9e1-46e5-9327-3dcb1eaf3e39

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 633; copy number 1: 22,970; copy number 2: 29,946; copy number 3: 1,983; copy number 4: 3,286; copy number 5: 27; copy number 6: 4; copy number 7: 15; copy number 17: 33; copy number 30: 8; copy number 36: 7.

Homozygous deletions (total copy number 0; autosomes only): 108 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:107,902,997–107,904,241, 2 genes: AC009963.2, AC009963.1.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr8:30,678,066–30,814,314, 4 genes: GSR, UBXN8, HIKESHIP3, PPP2CB.
- chr8:46,028,804–46,028,892, 1 gene: AC118650.1.
- chr16:1,148,224–1,148,754, 1 gene: AC120498.8.
- chr16:46,469,341–46,621,379, 5 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1.
- chr17:20,543,481–22,706,703, 87 genes (broad region; genes not listed).
- chr19:43,166,256–43,186,536, 1 gene: PSG5.
- chr21:13,038,160–13,113,790, 3 genes: ANKRD30BP2, RNU6-614P, ZNF355P.
- chr21:43,115,334–43,115,709, 1 gene: MRPL51P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 94 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,700,151–149,700,296, 1 gene, copy number 6 (within-gene range 6–7): RNU1-68P.
- chr3:75,521,803–75,522,012, 1 gene, copy number 5: SNRPCP10.
- chr5:135,802,985–135,803,075, 1 gene, copy number 6: MIR5692C1.
- chr7:46,476,457–46,759,851, 4 genes, copy number 5–6: AC004869.2, AC004869.1, HMGN1P19, AC011294.1.
- chr7:50,095,883–50,405,101, 6 genes, copy number 5 (within-gene range 3–5): SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1.
- chr7:54,752,250–55,678,490, 17 genes, copy number 5–36: SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1.
- chr7:56,060,470–56,229,782, 8 genes, copy number 30: SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1.
- chr7:56,597,379–56,603,553, 2 genes, copy number 5: AC092447.1, AC092447.9.
- chr8:79,259,402–81,284,777, 48 genes, copy number 7–17: AC138646.1, AC100870.1, RPL3P9, STMN2, HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr21:43,140,523–43,141,092, 1 gene, copy number 5: FRGCA.
- chr22:21,379,382–21,396,590, 5 genes, copy number 5: Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 20,642. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
